Somatic mutation profile of tumor specimen TCGA-VQ-A94T-01A (aliquot TCGA-VQ-A94T-01A-11D-A410-08) from TCGA case TCGA-VQ-A94T, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Carcinoma, diffuse type; Tissue or organ of origin: Cardia, NOS; AJCC pathologic stage: Stage IIIB; Tumor grade: G3; Age at diagnosis: 73.1 years (26,702 days).
Specimen TCGA-VQ-A94T-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fbcea121-2a5f-489b-a9a8-8a5a02d59853.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-VQ-A94T-10A (Blood Derived Normal), aliquot TCGA-VQ-A94T-10A-01D-A413-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b716dcfc-91dc-48ba-8fd1-60c490b3053c

The open-access MAF lists 81 somatic variants for this specimen: 58 protein-altering or splice-affecting, 23 silent.
By variant classification: Missense Mutation 47, Silent 23, Nonsense Mutation 4, Frame Shift Del 2, Splice Site 2, In Frame Del 2, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 20/65 reads (31%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- AOAH | c.277G>T p.D93Y | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT tolerated (0.15); PolyPhen benign (0.033); catalogued as rs1267800979, COSV99332373; called by muse, mutect2, varscan2
- AP2A2 | c.2421G>A p.R807= | Splice Region (SNP) | VAF 6/20 reads (30%) | catalogued as COSV100172636; called by muse, mutect2
- ARHGAP24 | c.1753G>T p.G585W (on ENST00000395184 / NM_001025616.3; = p.G492W on NM_031305.3) | Missense Mutation (SNP) | VAF 32/80 reads (40%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.621); catalogued as rs750379979, COSV51993294; called by muse, mutect2, varscan2
- ATP6V1H | c.163A>G p.M55V | Missense Mutation (SNP) | VAF 44/224 reads (20%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as rs752026205, COSV100778621; called by muse, mutect2, varscan2
- ATP7A | c.281C>T p.A94V | Missense Mutation (SNP) | VAF 81/249 reads (33%) | SIFT tolerated (0.26); PolyPhen benign (0.135); catalogued as rs1557231591, COSV58451871; called by muse, mutect2, varscan2
- AVIL | c.886A>G p.K296E | Missense Mutation (SNP) | VAF 10/63 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV99142226; called by muse, mutect2, varscan2
- CACHD1 | c.3509C>T p.A1170V | Missense Mutation (SNP) | VAF 18/45 reads (40%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.959); catalogued as rs1429142528, COSV99261750; called by muse, mutect2, varscan2
- CARD11 | c.509G>A p.R170H | Missense Mutation (SNP) | VAF 33/89 reads (37%) | SIFT tolerated (0.13); PolyPhen benign (0.172); catalogued as rs766268425, COSV62716853, COSV62719430, COSV62719971; called by muse, mutect2, varscan2
- CCNF | c.2113G>A p.V705I | Missense Mutation (SNP) | VAF 16/31 reads (52%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.005); catalogued as rs142923904; called by muse, mutect2, varscan2
- CDADC1 | c.1196C>T p.A399V | Missense Mutation (SNP) | VAF 57/113 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.834); catalogued as rs976194726, COSV51913459, COSV99212537; called by muse, mutect2, varscan2
- CDH7 | c.1589A>G p.N530S | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT tolerated (0.14); PolyPhen benign (0.112); catalogued as rs749778103, COSV100541740; called by muse, mutect2, varscan2
- COCH | c.954G>T p.Q318H (on ENST00000216361 / NM_001347720.1; = p.Q253H on NM_004086.3) | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); catalogued as COSV99363470; called by muse, mutect2, varscan2
- CTAG2 | c.472G>A p.A158T | Missense Mutation (SNP) | VAF 18/53 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.11); catalogued as rs199533324, COSV99908851; called by muse, mutect2, varscan2
- CYB5R2 | c.307A>G p.T103A | Missense Mutation (SNP) | VAF 28/60 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.491); catalogued as rs773767925, COSV100207376; called by muse, mutect2, varscan2
- FABP6 | c.91C>T p.R31W | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.981); catalogued as rs749950103, COSV101221174; called by muse, mutect2, varscan2
- FAT4 | c.12232G>A p.D4078N | Missense Mutation (SNP) | VAF 69/166 reads (42%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); catalogued as COSV100627719; called by muse, mutect2, varscan2
- FGF9 | c.328G>A p.V110M | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.847); catalogued as rs774141078, COSV66645453, COSV66645564; called by muse, mutect2, varscan2
- FTMT | c.679G>A p.E227K | Missense Mutation (SNP) | VAF 19/113 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.607); catalogued as COSV100360275, COSV58421075; called by muse, mutect2, varscan2
- GJB7 | c.644T>A p.L215* | Nonsense Mutation (SNP) | VAF 16/62 reads (26%) | catalogued as rs774378193, COSV99738153; called by muse, mutect2, varscan2
- GLB1 | c.1963A>C p.K655Q | Missense Mutation (SNP) | VAF 12/83 reads (14%) | SIFT tolerated (0.27); PolyPhen benign (0.003); catalogued as COSV100257077; called by muse, mutect2, varscan2
- GNLY | c.310C>T p.R104C | Missense Mutation (SNP) | VAF 15/56 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as rs751588471, COSV55703558; called by muse, mutect2, varscan2
- GPRASP1 | c.949T>G p.F317V | Missense Mutation (SNP) | VAF 77/91 reads (85%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as COSV100850942; called by muse, mutect2, varscan2
- HNRNPUL2 | c.634C>T p.R212* | Nonsense Mutation (SNP) | VAF 20/98 reads (20%) | catalogued as COSV99584567; called by muse, mutect2, varscan2
- HPX | c.766C>T p.R256C | Missense Mutation (SNP) | VAF 14/31 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs764755181, COSV56420018; called by muse, mutect2, varscan2
- HYDIN | c.14102G>A p.R4701H | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.966); catalogued as rs371498063, COSV101124976; called by muse, mutect2, varscan2
- KALRN | c.8723G>A p.S2908N (on ENST00000360013 / NM_001024660.4; = p.S1211N on NM_007064.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 36/60 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV99361437; called by muse, mutect2, varscan2
- KPNA6 | c.4G>C p.E2Q | Missense Mutation (SNP) | VAF 17/71 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0.047); catalogued as COSV101012457; called by muse, mutect2, varscan2
- LHX3 | c.436G>A p.E146K (on ENST00000371748 / NM_178138.6; = p.E151K on NM_014564.5) | Missense Mutation (SNP) | VAF 14/70 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as COSV65583249; called by muse, mutect2, varscan2
- LRRC18 | c.221A>G p.N74S | Missense Mutation (SNP) | VAF 26/35 reads (74%) | SIFT tolerated (0.5); PolyPhen benign (0.038); catalogued as COSV99628852; called by muse, mutect2, varscan2
- MAGIX | c.500G>A p.R167H | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.997); catalogued as rs782556687, COSV66255666; called by muse, mutect2, varscan2
- MAP2 | c.3925G>A p.V1309M | Missense Mutation (SNP) | VAF 16/82 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs764541712, COSV52291587, COSV52297582, COSV99558673; called by muse, mutect2, varscan2
- MLIP | c.314T>C p.I105T | Missense Mutation (SNP) | VAF 11/79 reads (14%) | SIFT tolerated (0.64); PolyPhen benign (0.011); catalogued as COSV99228774; called by muse, mutect2, varscan2
- MOGAT2 | c.77_79del p.S26del | In Frame Del (DEL) | VAF 11/34 reads (32%) | catalogued as rs764031531; called by mutect2, pindel, varscan2
- MSH3 | c.2814-1G>A p.X938_splice | Splice Site (SNP) | VAF 4/48 reads (8%) | catalogued as COSV99432750; called by muse, mutect2
- MYH9 | c.4753A>C p.K1585Q | Missense Mutation (SNP) | VAF 53/78 reads (68%) | SIFT tolerated (0.08); PolyPhen benign (0.411); catalogued as rs149169068; called by muse, mutect2, varscan2
- NDFIP1 | c.112G>T p.A38S | Missense Mutation (SNP) | VAF 54/134 reads (40%) | SIFT tolerated (0.72); PolyPhen benign (0.012); catalogued as rs1157700023, COSV99551053; called by muse, mutect2, varscan2
- NDST3 | c.2399+1G>T p.X800_splice | Splice Site (SNP) | VAF 20/96 reads (21%) | catalogued as rs1481295620, COSV56612925; called by muse, mutect2
- OR13C4 | c.563C>T p.A188V | Missense Mutation (SNP) | VAF 12/88 reads (14%) | SIFT tolerated (0.1); PolyPhen benign (0.411); catalogued as COSV99470053; called by muse, mutect2, varscan2
- PAM | c.1288G>T p.V430F | Missense Mutation (SNP) | VAF 12/91 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.017); catalogued as COSV99173170; called by muse, mutect2, varscan2
- PRR12 | c.3292G>T p.E1098* (on ENST00000615927; = p.E1919* on NM_020719.3) | Nonsense Mutation (SNP) | VAF 10/69 reads (14%) | catalogued as COSV101330584, COSV101330597; called by muse, mutect2, varscan2
- SEMA3A | c.742C>A p.R248S | Missense Mutation (SNP) | VAF 22/125 reads (18%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.918); catalogued as rs767094428; called by muse, mutect2, varscan2
- SGPP2 | c.930T>G p.I310M | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT tolerated (0.14); PolyPhen benign (0.034); catalogued as COSV100346222; called by muse, mutect2, varscan2
- STN1 | c.407G>A p.G136D | Missense Mutation (SNP) | VAF 28/82 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1360935761, COSV56545787; called by muse, mutect2, varscan2
- STXBP5L | c.2275C>T p.P759S | Missense Mutation (SNP) | VAF 17/64 reads (27%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.968); catalogued as COSV99872736; called by muse, mutect2, varscan2
- SYT6 | c.971G>A p.R324H (on ENST00000610222 / NM_001366225.1; = p.R239H on NM_205848.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 19/39 reads (49%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); catalogued as rs200072587, COSV65775348; called by muse, mutect2, varscan2
- TCOF1 | c.419C>T p.P140L | Missense Mutation (SNP) | VAF 24/44 reads (55%) | SIFT tolerated (0.09); PolyPhen benign (0.028); catalogued as COSV100077057; called by muse, mutect2, varscan2
- TEX11 | c.358C>T p.R120* (on ENST00000344304; = p.R105* on NM_031276.3) | Nonsense Mutation (SNP) | VAF 11/21 reads (52%) | catalogued as rs1486675411, COSV60228091, COSV60228924; called by muse, mutect2, varscan2
- TRDMT1 | c.1066C>T p.P356S | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT tolerated (0.22); PolyPhen benign (0.001); catalogued as rs1425396391, COSV58320905; called by muse, mutect2, varscan2
- TTN | c.86056C>A p.P28686T (on ENST00000591111; = p.P21262T on NM_003319.4) | Missense Mutation (SNP) | VAF 58/106 reads (55%) | PolyPhen benign (0.154); catalogued as COSV60214260; called by muse, mutect2, varscan2
- WDR17 | c.1096G>A p.V366M | Missense Mutation (SNP) | VAF 74/221 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.646); catalogued as rs753004304, COSV54571384; called by muse, mutect2, varscan2
- WNK1 | c.1430C>T p.A477V | Missense Mutation (SNP) | VAF 19/91 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.931); catalogued as rs1441069884, COSV100266633; called by muse, mutect2, varscan2
- XPNPEP1 | c.1049G>A p.R350H | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.943); catalogued as rs527414795, COSV59168673; called by muse, mutect2, varscan2
- ZNF667 | c.263C>A p.S88Y | Missense Mutation (SNP) | VAF 20/139 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.088); catalogued as COSV99410150; called by muse, mutect2, varscan2
- ZNF681 | c.1204G>T p.A402S | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.845); catalogued as COSV101267419; called by muse, mutect2, varscan2
- KIAA1522 | c.1722_1723del p.C575Ffs*5 (on ENST00000373480 / NM_001198972.2; = p.C634Ffs*5 on NM_020888.3) | Frame Shift Del (DEL) | VAF 24/54 reads (44%) | called by mutect2, pindel, varscan2
- MUC6 | c.6424_6427del p.S2142Lfs*33 | Frame Shift Del (DEL) | VAF 14/30 reads (47%) | called by mutect2, pindel, varscan2
- NIBAN2 | c.1083_1097del p.R362_F366del | In Frame Del (DEL) | VAF 10/82 reads (12%) | called by pindel, varscan2
- CCDC127 | c.498C>A p.L166= | Silent (SNP) | VAF 15/66 reads (23%) | catalogued as COSV99722912; called by muse, mutect2, varscan2
- CCKBR | c.183C>T p.Y61= | Silent (SNP) | VAF 18/60 reads (30%) | catalogued as COSV58099318; called by muse, mutect2, varscan2
- CNTRL | c.2325T>C p.L775= | Silent (SNP) | VAF 35/88 reads (40%) | catalogued as COSV99441535; called by muse, mutect2, varscan2
- DOCK3 | c.3588C>T p.L1196= | Silent (SNP) | VAF 31/105 reads (30%) | catalogued as COSV99810130; called by muse, mutect2, varscan2
- GPR18 | c.414C>T p.A138= | Silent (SNP) | VAF 7/51 reads (14%) | catalogued as rs374299759; called by muse, mutect2, varscan2
- HGS | c.1272G>A p.K424= | Silent (SNP) | VAF 15/43 reads (35%) | catalogued as rs766313878, COSV100230319, COSV100230572; called by muse, mutect2, varscan2
- KCND2 | c.795C>T p.I265= | Silent (SNP) | VAF 14/56 reads (25%) | catalogued as rs776818004, COSV58574107, COSV58596500; called by muse, mutect2, varscan2
- MCM10 | c.651G>T p.T217= (on ENST00000484800 / NM_182751.3; = p.T216= on NM_018518.5) | Silent (SNP) | VAF 53/68 reads (78%) | catalogued as rs568860384, COSV66335707; called by muse, mutect2, varscan2
- MINAR1 | c.2619C>T p.Y873= | Silent (SNP) | VAF 8/34 reads (24%) | catalogued as rs765175596, COSV100548747; called by muse, mutect2, varscan2
- OPRM1 | c.159C>T p.G53= | Silent (SNP) | VAF 9/35 reads (26%) | catalogued as COSV100000785; called by muse, mutect2, varscan2
- OR7E24 | c.148C>T p.L50= | Silent (SNP) | VAF 40/53 reads (75%) | catalogued as COSV101509643; called by muse, mutect2, varscan2
- PLD1 | c.1038C>T p.I346= | Silent (SNP) | VAF 18/64 reads (28%) | catalogued as rs1560238524, COSV100577809; called by muse, mutect2, varscan2
- PLEKHG4B | c.2577C>T p.H859= (on ENST00000283426; = p.H1215= on NM_052909.5) | Silent (SNP) | VAF 32/105 reads (30%) | catalogued as rs369268321; called by muse, mutect2, varscan2
- PRLR | c.360C>T p.D120= | Silent (SNP) | VAF 72/174 reads (41%) | catalogued as rs745809333, COSV51492857, COSV51496691; called by muse, mutect2, varscan2
- PTPRJ | c.2721C>T p.D907= | Silent (SNP) | VAF 40/156 reads (26%) | catalogued as rs532049445, COSV69255251; called by muse, mutect2, varscan2
- RTN4IP1 | c.108C>A p.T36= | Silent (SNP) | VAF 21/93 reads (23%) | catalogued as COSV100945194; called by muse, mutect2, varscan2
- TIGD3 | c.156G>A p.K52= | Silent (SNP) | VAF 19/78 reads (24%) | catalogued as COSV99361439; called by muse, mutect2, varscan2
- TMEM35A | c.420T>C p.S140= | Silent (SNP) | VAF 21/61 reads (34%) | catalogued as COSV99515135; called by muse, mutect2, varscan2
- TSHZ3 | c.156C>T p.L52= | Silent (SNP) | VAF 35/46 reads (76%) | catalogued as rs774598254, COSV99550979; called by muse, mutect2, varscan2
- UBR4 | c.675A>T p.S225= | Silent (SNP) | VAF 9/98 reads (9%) | catalogued as COSV100920595; called by muse, mutect2, varscan2
- UNC5CL | c.1410G>A p.E470= | Silent (SNP) | VAF 17/60 reads (28%) | catalogued as rs778438173, COSV99770673; called by muse, mutect2, varscan2
- ZEB2 | c.519C>T p.A173= | Silent (SNP) | VAF 17/55 reads (31%) | catalogued as rs1363607027, COSV100355464; called by muse, mutect2, varscan2
- ZNF880 | c.1080C>T p.V360= | Silent (SNP) | VAF 15/33 reads (45%) | catalogued as rs759670857, COSV69906060; called by muse, mutect2, varscan2
